Gene-level copy-number profile of tumor specimen ALCH-B2PW-TTP1-A from ALCHEMIST case ALCH-B2PW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.7 years (19,971 days).
Specimen ALCH-B2PW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b40240f8-c253-43d2-991b-8c42ecf47f3a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2PW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,265 have no estimate.
https://portal.gdc.cancer.gov/files/226f272e-9812-4a5e-a960-226743809c7c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 275; copy number 1: 7,875; copy number 2: 41,852; copy number 3: 8,162; copy number 4: 161; copy number 5: 1; copy number 6: 15; copy number 7: 2; copy number 8: 5; copy number 9: 3; copy number 11: 1; copy number 12: 1; copy number 16: 2; copy number 34: 1; copy number 38: 2.

Homozygous deletions (total copy number 0; autosomes only): 92 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,220,727–90,367,699, 6 genes: IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr2:91,589,494–91,659,972, 2 genes: AC116050.1, LSP1P4.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr9:20,331,446–23,438,700, 70 genes (broad region; genes not listed).
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr9:61,898,805–61,911,022, 1 gene: FAM242E.
- chr9:121,519,816–121,520,424, 1 gene: HMGB1P37.
- chr9:123,485,529–123,493,156, 2 genes (within-gene range 0–2): MIR7150, AL445489.1.
- chr9:136,712,572–136,724,742, 1 gene (within-gene range 0–3): DIPK1B.
- chr14:18,333,726–18,412,264, 3 genes: CR383658.1, RNU6-458P, CR383658.2.
- chr14:105,672,308–105,673,314, 1 gene (within-gene range 0–2): ELK2AP.
- chr17:81,003,335–81,005,132, 1 gene (within-gene range 0–2): AC127496.7.
- chr22:17,329,034–17,329,232, 1 gene: CECR9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 33 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:60,914,407–60,964,196, 5 genes, copy number 6: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr9:136,483,495–136,486,067, 1 gene, copy number 8 (within-gene range 1–8): C9orf163.
- chr9:136,738,167–136,766,255, 6 genes, copy number 6–11: LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15.
- chr9:136,848,724–136,860,799, 2 genes, copy number 16 (within-gene range 2–26): PHPT1, MAMDC4.
- chr9:136,969,243–136,985,435, 3 genes, copy number 6–38 (within-gene range 1–38): LINC02692, PTGDS, AL807752.7.
- chr9:137,007,234–137,028,922, 1 gene, copy number 8 (within-gene range 2–8): ABCA2.
- chr14:105,093,609–105,100,131, 2 genes, copy number 8: LINC02298, AL512356.4.
- chr14:105,621,116–105,621,180, 1 gene, copy number 34: MIR8071-1.
- chr14:105,647,924–105,649,057, 1 gene, copy number 9: COPDA1.
- chr17:81,029,130–81,034,881, 1 gene, copy number 9: BAIAP2-DT.
- chr19:1,228,287–1,279,244, 7 genes, copy number 6–12 (within-gene range 4–14): CBARP, AC004221.1, ATP5F1D, MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr20:50,247,643–50,321,342, 3 genes, copy number 5–6: PELATON, LINC01270, LINC01271.

Autosomal genes at a single copy (total copy number 1): 6,362. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
